Somatic mutation profile of tumor specimen 0E1HF9 from CCDI case PBCWIM, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male.
Specimen 0E1HF9: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 59f0057c-7ee9-4610-beea-362eaa6b1433.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0E1HG3 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/54189634-b74d-40ac-8c69-96597093ab88

The open-access MAF lists 4 somatic variants for this specimen: 3 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 3, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CYP4F22 | c.793C>T p.R265W | Missense Mutation (SNP) | VAF 117/238 reads (49%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.903); catalogued as rs144569785; called by muse, varscan2
- MYH9 | c.5873C>A p.P1958H | Missense Mutation (SNP) | VAF 62/140 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.036); called by muse, varscan2
- OAS3 | c.866A>G p.K289R | Missense Mutation (SNP) | VAF 71/206 reads (34%) | SIFT tolerated (0.44); PolyPhen benign (0.007); called by muse, varscan2
- CDH22 | c.402G>A p.T134= | Silent (SNP) | VAF 66/154 reads (43%) | catalogued as rs752285113; called by muse, varscan2
